Gene-level copy-number profile of tumor specimen TCGA-XF-AAMT-01A from TCGA case TCGA-XF-AAMT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 75.0 years (27,397 days).
Specimen TCGA-XF-AAMT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3fa9dbc7-76a0-4ab8-865c-eaeaf9c4de28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/772cb62e-745c-475b-a961-bb0316e700d6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 80; copy number 2: 15,900; copy number 3: 11,941; copy number 4: 24,878; copy number 5: 3,350; copy number 6: 2,384; copy number 7: 1,171; copy number 12: 10; copy number 13: 13; copy number 18: 78; copy number 29: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMT-01A-11D-A42D-01): tumor purity 0.56, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:3,250,687–3,627,296, 1 gene (within-gene range 0–2): AC034195.1.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 94 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:43,866,558–43,956,136, 4 genes, copy number 12 (within-gene range 6–12): URGCP-MRPS24, URGCP, TUBG1P, UBE2D4.
- chr11:81,821,272–82,718,299, 1 gene, copy number 12 (within-gene range 4–12): MIR4300HG.
- chr11:82,603,529–82,817,741, 5 genes, copy number 12 (within-gene range 7–12): AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3.
- chr17:20,008,865–21,594,180, 84 genes, copy number 13–18 (within-gene range 2–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 80. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
